EXCEPTIONAL_RESPONDERS case ER-B0BP — Exceptional Responders (EXCEPTIONAL_RESPONDERS-ER)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/80820e41-1efb-4ab7-bb87-09acc16f65c8

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1946; Vital status: Alive.

Diagnoses (2)
1. Diagnosis record without a diagnosis name: Tissue or organ of origin: Breast, NOS; Age at diagnosis: 55.1 years (20,127 days); AJCC pathologic stage: Stage IIIB.
2. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Lung, NOS; Classification of tumor: metastasis; Age at diagnosis: 66.6 years (24,336 days); Year of diagnosis: 2013; AJCC staging edition: 7th; AJCC pathologic stage: Stage IV; Prior malignancy: yes; Days to last follow up: 1,331 days (3.6 years); Days to best overall response: 573 days (1.6 years); Best overall response: Complete Response.
   Treatment given: Therapeutic agents: Carboplatin + Paclitaxel; Days to treatment start: 13 days; Days to treatment end: 317 days.

Follow-up (1 entry)
- Days to follow up: 1,331 days (3.6 years); Disease response: Stable Disease; Progression or recurrence: No; Days progression-free: 1,331 days (3.6 years).

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ER-B0BP-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ER-B0BP-TTM1-A-1-0-S1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 10; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample ER-B0BP-TTM2-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ER-B0BP-TTM2-A-1-0-S1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 15; Percent stromal cells: 15; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
